Gene-level copy-number profile of tumor specimen TCGA-2G-AALX-01A from TCGA case TCGA-2G-AALX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.eda339e2-6c8e-49fe-872a-472de3330363.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AALX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ad1830a-3514-450b-b2a4-a2324b15ef62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 989; copy number 2: 29,472; copy number 3: 25,403; copy number 4: 135; copy number 5: 3,013; copy number 6: 331; copy number 8: 128; copy number 9: 316; copy number 25: 13; copy number 30: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AALX-01A-11D-A42X-01): tumor purity 0.84, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:121,769,761–122,174,099, 7 genes: IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, AC068630.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,463 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,455,568–196,536,702, 583 genes, copy number 5–8 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5–9 (broad region; genes not listed).
- chr20:31,257,664–31,723,989, 30 genes, copy number 6–30: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.

Autosomal genes at a single copy (total copy number 1): 989. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
